Somatic mutation profile of tumor specimen ALCH-B01I-TTP1-A (aliquot ALCH-B01I-TTP1-A-2-0-D-A679-36) from ALCHEMIST case ALCH-B01I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 64.4 years (23,537 days).
Specimen ALCH-B01I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38d25cd3-8697-4d06-995c-e046bb8635cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01I-NB1-A (Blood Derived Normal), aliquot ALCH-B01I-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/364bbc83-333a-49e6-8e7c-69820627ec50

The open-access MAF lists 161 somatic variants for this specimen: 121 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 25, Nonsense Mutation 12, Intron 4, 3'UTR 4, Splice Site 3, RNA 2, 5'UTR 2, IGR 1, Splice Region 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGB | c.4807A>C p.K1603Q | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs1247118907; called by muse, mutect2
- ASH1L | c.3844A>T p.R1282* | Nonsense Mutation (SNP) | VAF 20/286 reads (7%) | catalogued as COSV64210569; called by muse, mutect2
- ASTN2 | c.1169G>T p.G390V (on ENST00000313400 / NM_001365069.1; = p.G339V on NM_014010.5) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57795695; called by muse, mutect2
- C20orf202 | c.33C>A p.N11K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1028974052; called by muse, mutect2, varscan2
- C9 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs145819975, COSV99662829; called by muse, mutect2
- CASP8AP2 | c.3601G>T p.D1201Y | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs752646565, COSV99387080; called by muse, mutect2, varscan2
- COL11A1 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62185911; called by muse, mutect2
- COL5A2 | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415764; called by muse, mutect2
- CSMD3 | c.7024G>T p.G2342* (on ENST00000297405 / NM_001363185.1; = p.G2238* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 30/603 reads (5%) | catalogued as COSV52204955; called by muse, mutect2
- DIRAS3 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1215159107; called by muse, mutect2
- DNAH5 | c.12082G>T p.V4028F | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV99454070; called by muse, mutect2
- FAM135B | c.1850C>A p.T617N | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV52731970; called by muse, mutect2
- FBXL7 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1437379180, COSV100308860; called by muse, mutect2
- GPRASP2 | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59992476; called by muse, mutect2
- GRM1 | c.2601C>A p.C867* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as rs1442641355; called by muse, mutect2
- HTR3E | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1354405080; called by muse, mutect2
- IKZF2 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563797; called by muse, mutect2
- ITPR1 | c.3924G>C p.Q1308H (on ENST00000354582; = p.Q1293H on NM_002222.7) | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV56996090; called by muse, mutect2
- LILRA2 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs957323047; called by muse, mutect2
- MAPK1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53187829; called by muse, mutect2
- MORN5 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1175478327, COSV65648575, COSV65649546; called by muse, mutect2
- MYO3A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 31/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772007643; called by muse, mutect2
- NCF4 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1248621440, COSV50625482; called by muse, mutect2
- NOSTRIN | c.1400T>C p.I467T (on ENST00000317647 / NM_001039724.4; = p.I389T on NM_052946.3) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1161662685, COSV100473429; called by muse, mutect2
- NPY1R | c.1066C>A p.H356N | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs935978780; called by muse, mutect2
- NTNG1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 23/442 reads (5%) | catalogued as COSV99637723, COSV99639652; called by muse, mutect2
- OR5D16 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as COSV65721277; called by muse, mutect2
- PKD1L3 | c.4996G>A p.V1666I | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1370980009; called by muse, mutect2
- RELN | c.4639C>G p.R1547G | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100634184; called by muse, mutect2
- RPL10L | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs758921040, COSV53558822, COSV53559285; called by muse, mutect2
- SLC25A23 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV99902401; called by muse, mutect2
- SLCO1B1 | c.1723C>G p.H575D | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV57009813; called by muse, mutect2, varscan2
- TENM2 | c.1465G>T p.A489S (on ENST00000518659 / NM_001122679.2; = p.A257S on NM_001080428.3) | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as rs764193780, COSV69127008; called by muse, mutect2
- TG | c.7281G>T p.E2427D | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV55079283; called by muse, mutect2
- TMC3 | c.2800C>A p.R934S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV63923369, COSV63924852; called by muse, mutect2, varscan2
- TMEM102 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV53439017; called by muse, varscan2
- TMEM200A | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51660952; called by muse, mutect2
- TRPM6 | c.2975G>C p.G992A | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62513302; called by muse, mutect2
- TSKS | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | catalogued as COSV99883251; called by muse, mutect2
- VAC14 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1048372050; called by muse, mutect2
- AC244197.3 | c.1008G>T p.L336F | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2
- ACTC1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRA2 | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP10 | c.238A>G p.M80V | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- AKAP8 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- ANKRD31 | c.5261G>T p.G1754V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- ASTN1 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC62 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); called by muse, varscan2
- CCL23 | c.302+2T>C p.X101_splice | Splice Site (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- CCSER1 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- CFAP157 | c.1414C>A p.P472T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CHD7 | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- CHRM2 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLIC1 | c.466A>C p.S156R | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- COL14A1 | c.3913C>T p.L1305F | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2
- CPNE4 | c.151A>C p.K51Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.555); called by muse, mutect2
- CRY2 | c.1460G>T p.R487L | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- CSMD3 | c.7787G>T p.C2596F (on ENST00000297405 / NM_001363185.1; = p.C2492F on NM_052900.3) | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.5711G>T p.C1904F (on ENST00000297405 / NM_001363185.1; = p.C1800F on NM_052900.3) | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- DCDC1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.193); called by muse, mutect2
- DMD | c.1608G>T p.L536F | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK10 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DPYS | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- DSPP | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.111); called by muse, mutect2
- ENAM | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- EYA1 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2
- FAM184B | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- GABRR3 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GBA3 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GP1BA | c.243C>A p.C81* | Nonsense Mutation (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- GPR78 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GYPA | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2
- HEXA | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 49/385 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGF2R | c.3845G>T p.C1282F | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGSF8 | c.567G>T p.R189S | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF8 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL1RAPL1 | c.137del p.G46Efs*29 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- IP6K3 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ISL1 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR2 | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- JAKMIP3 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.342); called by muse, mutect2
- KCNH1 | c.1021A>G p.R341G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- LRP2 | c.6219C>G p.I2073M | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- LRP2 | c.4457C>A p.T1486N | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2
- MAGEB4 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MAGEB5 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- MBD1 | c.639A>T p.R213S | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM2 | c.2394A>T p.E798D | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2
- MINDY3 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- MPDZ | c.2335G>T p.V779L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MRC2 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- MUC15 | c.788A>T p.K263I | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MYOT | c.634-4C>T | Splice Region (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- NPY1R | c.1068C>A p.H356Q | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- OR11H1 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 22/582 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR2L2 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- OR4K13 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.168); called by muse, mutect2
- PAK3 | c.1236G>T p.M412I (on ENST00000262836 / NM_001324328.2; = p.M397I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PLCB1 | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 7/226 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- PLCB1 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 7/220 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POGZ | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PTPRC | c.2939-2A>T p.X980_splice | Splice Site (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- RTL3 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SALL1 | c.1077T>A p.S359R | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- SIGLEC8 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by mutect2, varscan2
- SLC36A2 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.644); called by muse, mutect2
- SLC37A3 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTA1 | c.531+1G>T p.X177_splice | Splice Site (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- SRPX2 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- STARD8 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- STXBP5L | c.2126G>T p.R709L | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); called by muse, mutect2
- SYNE1 | c.21333G>T p.W7111C (on ENST00000367255 / NM_182961.4; = p.W7040C on NM_033071.3) | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TG | c.2915T>A p.L972H | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- TNNT3 | c.485G>A p.G162E (on ENST00000397301 / NM_001367846.1; = p.G151E on NM_006757.4) | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TPH1 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2
- TRIM58 | c.1254A>T p.E418D | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2
- TRIO | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 11/249 reads (4%) | called by muse, mutect2
- USP9Y | c.4690G>T p.A1564S | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.5858C>A p.A1953D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2
- ZNF331 | c.340A>T p.R114* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- ZNF850 | c.2155C>A p.H719N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ACOD1 | c.729G>T p.G243= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- ANK3 | c.5313T>A p.T1771= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- C6orf118 | c.144T>A p.L48= | Silent (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- CDH18 | c.1152C>A p.S384= | Silent (SNP) | VAF 43/448 reads (10%) | catalogued as COSV56939955; called by muse, varscan2
- CMPK2 | c.684C>T p.S228= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- DMD | c.9465C>T p.T3155= | Silent (SNP) | VAF 31/301 reads (10%) | called by muse, mutect2, varscan2
- GRIK1 | c.1959G>A p.G653= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV58720033; called by muse, mutect2
- GSDMC | c.42A>G p.K14= | Silent (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- HDX | c.1344C>A p.A448= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- IGSF10 | c.4677A>G p.K1559= | Silent (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- ILDR2 | c.228G>T p.R76= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as COSV54828419; called by muse, mutect2
- IRS4 | c.2259A>G p.P753= | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as rs1257949927; called by muse, mutect2
- KLK14 | c.552G>T p.T184= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as rs1332634918, COSV50070723; called by muse, mutect2
- NCSTN | c.975C>T p.V325= | Silent (SNP) | VAF 34/268 reads (13%) | called by muse, mutect2, varscan2
- OR4C12 | c.769C>T p.L257= | Silent (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- OTUD6B | c.789A>T p.L263= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- PRUNE2 | c.2784A>G p.K928= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs1362452469; called by muse, mutect2
- RBM11 | c.291A>G p.Q97= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- RYR2 | c.6093C>T p.S2031= | Silent (SNP) | VAF 10/323 reads (3%) | catalogued as COSV63700024; called by muse, mutect2
- TTN | c.54684A>G p.S18228= (on ENST00000591111; = p.S10804= on NM_003319.4) | Silent (SNP) | VAF 40/325 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.26214T>A p.G8738= (on ENST00000591111; = p.G7811= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- WDFY4 | c.3924T>C p.N1308= | Silent (SNP) | VAF 13/196 reads (7%) | called by muse, mutect2
- ZIM2 | c.1428T>C p.S476= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ZNF711 | c.1866G>A p.E622= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as COSV52159872; called by muse, mutect2
- ZNF778 | c.1374C>T p.F458= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- B4GALNT1 | c.*2658G>C | 3'UTR (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592568 G>A | 5'Flank (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- COL4A1 | c.553-18C>T | Intron (SNP) | VAF 20/417 reads (5%) | called by muse, mutect2
- DCHS2 | n.5296G>T | RNA (SNP) | VAF 11/300 reads (4%) | called by muse, mutect2
- EYA1 | c.1141-8237A>T | Intron (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- HMOX1 | c.-45G>A | 5'UTR (SNP) | VAF 9/96 reads (9%) | catalogued as rs1460617841; called by muse, mutect2
- HOXA7 | chr7:27152862 G>T | 3'Flank (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- KLC1 | c.*10392C>T | 3'UTR (SNP) | VAF 7/191 reads (4%) | called by muse, mutect2
- KRT9 | c.-19G>T | 5'UTR (SNP) | VAF 13/194 reads (7%) | catalogued as rs1304953715, COSV55855942; called by muse, mutect2
- MFAP5 | c.410-349C>T | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- RSPH9 | c.*1420C>A | 3'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100928795; called by muse, mutect2, varscan2
- SMARCA1 | c.*144C>T | 3'UTR (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-18 | n.22T>C | RNA (SNP) | VAF 13/204 reads (6%) | catalogued as rs933877633; called by muse, mutect2
- UGT3A1 | c.843+2439G>A | Intron (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- Unknown | chr2:217713059 T>A | IGR (SNP) | VAF 20/332 reads (6%) | called by muse, mutect2
